Somatic mutation profile of tumor specimen TCGA-NG-A4VU-01A (aliquot TCGA-NG-A4VU-01A-11D-A28R-08) from TCGA case TCGA-NG-A4VU, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIB; Age at diagnosis: 63.9 years (23,323 days).
Specimen TCGA-NG-A4VU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c1df2f2e-e744-4745-862b-0de794ea6eba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-NG-A4VU-10A (Blood Derived Normal), aliquot TCGA-NG-A4VU-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/684fa3b7-4219-4804-b753-d7686873e74e

The open-access MAF lists 39 somatic variants for this specimen: 29 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 27, Silent 10, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1513C>G p.R505G (on ENST00000281708 / NM_001349798.2; = p.R425G on NM_018315.5) | Missense Mutation (SNP) | VAF 38/84 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 46/47 reads (98%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADGRB3 | c.3810G>C p.L1270F | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as COSV53235162; called by muse, mutect2, varscan2
- ARHGAP35 | c.2587C>T p.R863C | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68330957; called by muse, mutect2, varscan2
- COQ8B | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs199930495; called by muse, mutect2, varscan2
- MAGEC2 | c.661G>C p.D221H | Missense Mutation (SNP) | VAF 52/61 reads (85%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.739); catalogued as COSV99910000; called by muse, mutect2, varscan2
- OR51A4 | c.869C>T p.P290L | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as rs1385660063, COSV66749790; called by muse, mutect2, varscan2
- OXTR | c.556G>A p.D186N | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761299103; called by muse, mutect2, varscan2
- PALLD | c.2600C>T p.T867I (on ENST00000505667 / NM_001166108.2; = p.T850I on NM_016081.4) | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1465496279; called by muse, mutect2, varscan2
- PCDHB6 | c.2171C>T p.S724L | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.187); catalogued as rs1453559918, COSV50690037; called by muse, mutect2
- TBC1D9B | c.2164G>A p.E722K | Missense Mutation (SNP) | VAF 51/55 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs763482090, COSV62281709; called by muse, mutect2, varscan2
- TUBAL3 | c.562G>A p.V188M | Missense Mutation (SNP) | VAF 52/87 reads (60%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.901); catalogued as rs782012870, COSV66814175; called by muse, mutect2, varscan2
- ADAMTS2 | c.2312G>T p.G771V | Missense Mutation (SNP) | VAF 37/40 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATP6V0A4 | c.2371G>C p.A791P | Missense Mutation (SNP) | VAF 99/217 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ATP8B2 | c.1523A>G p.H508R (on ENST00000672630; = p.H475R on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEACAM21 | c.842C>G p.S281C (on ENST00000401445 / NM_001098506.4; = p.S280C on NM_033543.6) | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- CEP170 | c.4001G>A p.S1334N | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by mutect2, varscan2
- DDX31 | c.2141-1G>A p.X714_splice | Splice Site (SNP) | VAF 19/35 reads (54%) | called by muse, mutect2, varscan2
- HEATR5B | c.4927A>G p.S1643G | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- IGKV6-21 | c.245G>A p.S82N | Missense Mutation (SNP) | VAF 43/194 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- NAA35 | c.862G>A p.D288N | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.63); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PEPD | c.97C>G p.R33G | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PLAA | c.1270G>A p.D424N | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- PPP2R1A | c.1237G>A p.E413K | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- RFX1 | c.751C>T p.Q251* | Nonsense Mutation (SNP) | VAF 104/187 reads (56%) | called by muse, mutect2, varscan2
- TET3 | c.5214G>C p.K1738N | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- TOPORS | c.92G>T p.S31I | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- UNC13C | c.248G>A p.S83N | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); called by muse, mutect2
- WRN | c.557G>T p.G186V | Missense Mutation (SNP) | VAF 24/24 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- AP1B1 | c.351G>A p.K117= | Silent (SNP) | VAF 8/23 reads (35%) | called by muse, mutect2, varscan2
- C5orf46 | c.132C>T p.D44= | Silent (SNP) | VAF 12/35 reads (34%) | called by muse, mutect2, varscan2
- CAVIN1 | c.816G>A p.K272= | Silent (SNP) | VAF 30/62 reads (48%) | called by muse, mutect2, varscan2
- DVL2 | c.1959G>C p.G653= | Silent (SNP) | VAF 39/44 reads (89%) | called by muse, mutect2, varscan2
- EIF3D | c.384G>A p.Q128= | Silent (SNP) | VAF 38/70 reads (54%) | called by muse, mutect2, varscan2
- PIGR | c.639C>T p.S213= | Silent (SNP) | VAF 24/99 reads (24%) | catalogued as rs761979881, COSV62903817; called by muse, mutect2, varscan2
- PPP1R18 | c.1765C>T p.L589= | Silent (SNP) | VAF 27/80 reads (34%) | called by muse, mutect2, varscan2
- RNASE2 | c.43C>T p.L15= | Silent (SNP) | VAF 38/159 reads (24%) | catalogued as COSV100482038; called by muse, mutect2, varscan2
- SRRM4 | c.891G>A p.T297= | Silent (SNP) | VAF 3/33 reads (9%) | catalogued as rs1460441902, COSV57412277; called by muse, mutect2
- THSD7B | c.1413G>A p.P471= | Silent (SNP) | VAF 43/99 reads (43%) | catalogued as rs376181717; called by muse, mutect2, varscan2
